Somatic mutation profile of tumor specimen TCGA-BR-7958-01A (aliquot TCGA-BR-7958-01A-21D-2340-08) from TCGA case TCGA-BR-7958, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 60.8 years (22,204 days).
Specimen TCGA-BR-7958-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31c4b4f5-2a5b-4e3c-bf1d-a43c67b7b5a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7958-10A (Blood Derived Normal), aliquot TCGA-BR-7958-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bb0ce74-cb21-46ef-a005-de5b1c7e45ec

The open-access MAF lists 181 somatic variants for this specimen: 133 protein-altering or splice-affecting, 42 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 42, Nonsense Mutation 6, Frame Shift Del 4, RNA 3, Splice Site 2, Intron 2, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD3 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 41/100 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs794727798, COSV59282451; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB6 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs757264353, COSV54699047; called by muse, mutect2, varscan2
- AC092143.1 | c.1828C>G p.L610V | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV59247982, COSV59248580; called by muse, mutect2, varscan2
- AC093827.5 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV55745576; called by muse, mutect2, varscan2
- ADAMTS10 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.921); catalogued as rs781891774, COSV54357783; called by muse, mutect2, varscan2
- ADAMTS13 | c.3202C>T p.L1068F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV63022625; called by muse, mutect2, varscan2
- AMPD1 | c.1491T>G p.D497E | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62417898; called by muse, mutect2, varscan2
- ARHGAP28 | c.1307T>C p.L436P (on ENST00000383472 / NM_001366230.1; = p.L277P on NM_001010000.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1214308156, COSV51632708, COSV51641871; called by muse, mutect2, varscan2
- ASIC4 | c.931T>G p.S311A | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV61732879; called by muse, mutect2, varscan2
- BCAT2 | c.414T>A p.S138R | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV100302407, COSV60273619; called by muse, mutect2
- BIRC6 | c.4525G>A p.D1509N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV70203899; called by muse, mutect2, varscan2
- BMP4 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.939); catalogued as rs755084602, COSV55416888; called by muse, mutect2, varscan2
- BMPR1B | c.1463A>G p.K488R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52780457; called by muse, mutect2, varscan2
- CASS4 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV64387388, COSV64387868; called by muse, mutect2, varscan2
- CCDC110 | c.1025A>C p.K342T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV56872812; called by muse, mutect2, varscan2
- CDH23 | c.7264C>G p.L2422V | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.083); catalogued as COSV56481703; called by muse, mutect2, varscan2
- CDH9 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50374477, COSV99147166; called by muse, mutect2, varscan2
- CFAP54 | c.4921C>T p.R1641W | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199535438, COSV61571429, COSV61574175; called by muse, mutect2, varscan2
- CHST9 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52435469, COSV52445674; called by muse, mutect2, varscan2
- COL14A1 | c.1034T>G p.I345S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52863930; called by muse, mutect2, varscan2
- COPS7A | c.665T>G p.V222G | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV57527140; called by muse, mutect2, varscan2
- COPZ1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV50431994; called by muse, mutect2, varscan2
- CSF2RB | c.2552T>C p.L851P | Missense Mutation (SNP) | VAF 92/362 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV53260096; called by muse, mutect2, varscan2
- CSMD1 | c.10237C>A p.L3413M (on ENST00000520002; = p.L3412M on NM_033225.6) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1340127454, COSV59363574; called by muse, mutect2, varscan2
- CSMD3 | c.3479T>G p.I1160S (on ENST00000297405 / NM_001363185.1; = p.I1056S on NM_052900.3) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52272918; called by muse, mutect2
- DLEC1 | c.2282A>T p.Y761F | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV57304579; called by muse, mutect2, varscan2
- DMD | c.165A>T p.E55D | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55892017; called by muse, mutect2, varscan2
- DMRTC2 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs782270959, COSV54186844, COSV54187886; called by muse, mutect2, varscan2
- EHD2 | c.164T>G p.F55C | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54410275; called by muse, mutect2, varscan2
- EIF4A1 | c.1184T>C p.I395T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV51511802; called by muse, mutect2, varscan2
- ELMO1 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV60317821; called by muse, mutect2, varscan2
- ERBB4 | c.2129T>G p.L710R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53530135; called by muse, mutect2, varscan2
- ESRRG | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs1217025239, COSV63174256; called by muse, mutect2, varscan2
- EVI5 | c.1842A>C p.K614N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.334); catalogued as COSV64829172; called by muse, mutect2, varscan2
- FHOD3 | c.2015T>C p.L672P (on ENST00000359247 / NM_001281739.3; = p.L689P on NM_025135.5) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV57183155; called by muse, mutect2, varscan2
- FLG2 | c.6834A>C p.Q2278H | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); catalogued as COSV66168605, COSV66171573; called by muse, mutect2, varscan2
- FNDC1 | c.5595G>T p.E1865D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51945117; called by muse, mutect2, varscan2
- FNDC7 | c.1919G>A p.G640D | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.412); catalogued as COSV54756636; called by muse, mutect2, varscan2
- FREM2 | c.4022A>C p.Y1341S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54847173; called by muse, mutect2, varscan2
- GDNF | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58480986; called by muse, mutect2, varscan2
- GPRC6A | c.1117A>T p.S373C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as COSV59955123; called by muse, mutect2, varscan2
- GRIK2 | c.1786A>C p.N596H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV59759422; called by muse, mutect2, varscan2
- GRK2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV57953371, COSV57953800; called by muse, mutect2, varscan2
- GRXCR1 | c.283A>G p.R95G | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV67673654; called by muse, mutect2, varscan2
- IFNA10 | c.390A>C p.E130D | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV99497554; called by muse, mutect2, varscan2
- IGLC7 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.699); catalogued as rs768768792; called by muse, mutect2, varscan2
- IL17RB | c.1046G>C p.C349S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs749776929, COSV51638023; called by muse, mutect2, varscan2
- JCHAIN | c.393C>A p.C131* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV54659649; called by muse, mutect2, varscan2
- KCND3 | c.1159T>C p.C387R | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56186712; called by muse, mutect2, varscan2
- KCNT1 | c.2749G>A p.D917N (on ENST00000488444; = p.D936N on NM_020822.3) | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV53699304; called by muse, mutect2, varscan2
- KIF9 | c.1753A>G p.K585E (on ENST00000265529 / NM_001377474.1; = p.K520E on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55522487; called by muse, mutect2, varscan2
- KLHL2 | c.728A>T p.E243V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56981183; called by muse, mutect2, varscan2
- KLHL38 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.044); catalogued as COSV58088583; called by muse, mutect2, varscan2
- KMT2A | c.5000C>T p.A1667V | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV63290519; called by muse, mutect2, varscan2
- KRTAP10-4 | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV59952056, COSV59973994; called by muse, mutect2, varscan2
- LHCGR | c.1815A>C p.K605N | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54298497; called by muse, mutect2, varscan2
- LRP1B | c.5018C>T p.T1673M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs199519370, COSV67279819; called by muse, mutect2, varscan2
- LRRC4B | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs761399852, COSV65350316; called by muse, mutect2, varscan2
- LYG1 | c.404C>G p.T135S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.23); catalogued as COSV57915866, COSV57915958; called by muse, mutect2, varscan2
- LYST | c.7349T>G p.L2450R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV67703842; called by muse, mutect2, varscan2
- MFSD3 | c.948C>G p.I316M | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV56742553; called by muse, mutect2, varscan2
- MPP2 | c.664C>T p.R222C (on ENST00000461854 / NM_001278372.2; = p.R198C on NM_005374.5) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs752282662, COSV52238866; called by muse, mutect2, varscan2
- MRC2 | c.2509T>A p.Y837N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57642735, COSV57643073; called by muse, mutect2, varscan2
- MUC16 | c.33236C>T p.A11079V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV67483443; called by muse, mutect2, varscan2
- MYH11 | c.2565G>C p.Q855H | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV55564285; called by muse, mutect2, varscan2
- NASP | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as COSV59646794; called by muse, mutect2, varscan2
- NDNF | c.1314G>C p.R438S | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV65634419; called by muse, mutect2, varscan2
- NIN | c.1370A>G p.Q457R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs747774884, COSV55401304; called by muse, mutect2, varscan2
- NMBR | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as COSV57802735; called by muse, mutect2, varscan2
- NOBOX | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV56196751; called by muse, mutect2, varscan2
- NPAT | c.2686C>A p.P896T | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV53720435; called by muse, mutect2
- NPTX1 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as rs775120856, COSV60776074; called by muse, mutect2, varscan2
- OR13A1 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1480657367, COSV65573070; called by muse, mutect2, varscan2
- OR3A3 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52168226; called by muse, mutect2, varscan2
- OR52E4 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.48); catalogued as COSV57625719; called by muse, mutect2, varscan2
- P3H2 | c.2092C>G p.H698D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV60026062; called by muse, mutect2
- PCDHB13 | c.913A>C p.K305Q | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.255); catalogued as COSV53399594; called by muse, mutect2, varscan2
- PFDN5 | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs199718276, COSV54475184, COSV99229210; called by muse, mutect2, varscan2
- PHLDA2 | c.270G>T p.W90C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56541252; called by muse, mutect2, varscan2
- PLEKHN1 | c.1400G>A p.R467Q (on ENST00000379409; = p.R415Q on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as rs753141005, COSV58023287; called by muse, mutect2, varscan2
- PLXNA4 | c.664T>G p.F222V | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58151296; called by muse, mutect2, varscan2
- PPP3CA | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 87/377 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59928897; called by muse, mutect2, varscan2
- PRMT1 | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.845); catalogued as COSV54921416; called by muse, mutect2, varscan2
- R3HCC1L | c.1717A>T p.I573F | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54404254; called by muse, mutect2
- RASGEF1C | c.738C>G p.S246R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV63183416; called by muse, mutect2, varscan2
- RCBTB1 | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV51636163; called by muse, mutect2, varscan2
- RPL15 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV57140167; called by muse, mutect2, varscan2
- RSBN1L | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV58510333; called by muse, mutect2, varscan2
- RTL3 | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.368); catalogued as COSV58183560, COSV58185228; called by muse, mutect2
- SAPCD1 | c.273A>C p.L91F | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV65173950; called by muse, mutect2, varscan2
- SCN3A | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142323631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINF2 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.051); catalogued as rs767167105, COSV60665311; called by muse, mutect2, varscan2
- SLC35F2 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as rs374138023; called by muse, mutect2, varscan2
- SLC7A1 | c.1101G>T p.E367D | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.168); catalogued as COSV66330860; called by muse, mutect2
- SLCO5A1 | c.932T>G p.L311R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52665246, COSV99479227; called by muse, mutect2, varscan2
- SMAD4 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61690386; called by muse, mutect2, varscan2
- SNX21 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs374495414; called by muse, mutect2, varscan2
- SRCAP | c.9114G>C p.L3038F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV52678448; called by muse, mutect2, varscan2
- STAB2 | c.4384T>A p.F1462I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs1265148367, COSV101186175; called by muse, mutect2, varscan2
- TARDBP | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV53570874; called by muse, mutect2, varscan2
- TBC1D8B | c.2684T>C p.F895S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52182096; called by muse, mutect2, varscan2
- TBC1D9B | c.3628G>A p.E1210K (on ENST00000356834 / NM_198868.3; = p.E1193K on NM_015043.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1397474201, COSV52974726; called by muse, mutect2, varscan2
- THNSL1 | c.1232G>C p.G411A | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64479741; called by muse, mutect2, varscan2
- TNFSF11 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53479043; called by muse, mutect2, varscan2
- TOLLIP | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as rs765578822, COSV55137793; called by muse, mutect2, varscan2
- TRIM6 | c.200A>C p.N67T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV53476059, COSV53478143; called by muse, mutect2, varscan2
- TRMT13 | c.1109G>A p.W370* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | catalogued as rs1234349711, COSV61583681; called by muse, mutect2, varscan2
- TRPC5 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390654922, COSV53290917; called by muse, mutect2, varscan2
- TSNAXIP1 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV54651457, COSV54651849; called by muse, mutect2, varscan2
- TTK | c.2447T>G p.L816R | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57885887; called by muse, mutect2, varscan2
- TTN | c.72263A>C p.K24088T (on ENST00000591111; = p.K16664T on NM_003319.4) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | PolyPhen possibly damaging (0.743); catalogued as COSV60250930; called by muse, mutect2, varscan2
- TTN | c.68788A>C p.T22930P (on ENST00000591111; = p.T15506P on NM_003319.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | PolyPhen benign (0.134); catalogued as COSV60250967; called by muse, mutect2, varscan2
- TTN | c.54338A>C p.K18113T (on ENST00000591111; = p.K10689T on NM_003319.4) | Missense Mutation (SNP) | VAF 24/155 reads (15%) | PolyPhen possibly damaging (0.6); catalogued as COSV100596298, COSV59923859; called by muse, mutect2, varscan2
- TUBA3C | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV67139777; called by muse, mutect2, varscan2
- TUBB2B | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV99455553; called by muse, mutect2, varscan2
- TUBGCP6 | c.3508A>G p.S1170G | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV50569936; called by muse, mutect2, varscan2
- TYRO3 | c.2329C>G p.P777A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55485919; called by muse, mutect2, varscan2
- ULBP1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57664780; called by muse, mutect2, varscan2
- UTRN | c.8923C>T p.L2975F | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62305017; called by muse, mutect2, varscan2
- WDR26 | c.1708T>G p.F570V (on ENST00000414423 / NM_001379403.1; = p.F470V on NM_025160.7) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as COSV54358740; called by muse, mutect2, varscan2
- ZBTB20 | c.1667C>T p.A556V (on ENST00000474710 / NM_001164342.2; = p.A483V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1323958910, COSV61862518; called by muse, mutect2, varscan2
- ZBTB7A | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs77059506, COSV100475840; called by muse, varscan2
- ZNF646 | c.4090G>C p.V1364L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV54925949; called by muse, mutect2, varscan2
- ZWINT | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as COSV59186141; called by muse, mutect2, varscan2
- ALDH1L1 | c.1538_1551del p.A513Gfs*21 | Frame Shift Del (DEL) | VAF 33/216 reads (15%) | called by mutect2, pindel, varscan2
- CFHR2 | c.546_559del p.Y182* | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | called by mutect2, pindel, varscan2
- KYNU | c.1080dup p.S361Ifs*15 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- LRRC8E | c.2117_2145del p.L706Rfs*91 | Frame Shift Del (DEL) | VAF 12/128 reads (9%) | called by mutect2, pindel
- MCM10 | c.1087_1101+5del p.X363_splice (on ENST00000484800 / NM_182751.3; = p.X362_splice on NM_018518.5) | Splice Site (DEL) | VAF 14/118 reads (12%) | called by mutect2, pindel
- SYNE2 | c.5079_5080del p.S1694Rfs*4 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- TMEM266 | c.992_1018del p.I331_S339del | In Frame Del (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel
- TRAV10 | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WWC1 | c.721-38_722del p.X241_splice | Splice Site (DEL) | VAF 30/165 reads (18%) | called by mutect2, pindel
- ACOT2 | c.576C>T p.L192= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV53151223; called by muse, mutect2, varscan2
- AP1G1 | c.15C>T p.I5= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs1329615394, COSV55486549, COSV55493669; called by muse, mutect2, varscan2
- BOC | c.351C>T p.S117= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs758598582, COSV56355956; called by muse, mutect2, varscan2
- BRF2 | c.477C>A p.L159= | Silent (SNP) | VAF 99/405 reads (24%) | catalogued as COSV55104986; called by muse, mutect2, varscan2
- C1QTNF8 | c.139C>T p.L47= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV60519607; called by muse, mutect2, varscan2
- CACNB3 | c.1068C>T p.Y356= | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as rs773169224, COSV56400082; called by muse, mutect2, varscan2
- CCDC28A | c.147A>G p.P49= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs766471236, COSV100236585; called by muse, mutect2, varscan2
- CLRN1 | c.93G>A p.P31= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs773516153, COSV58996061; called by muse, mutect2, varscan2
- EHD1 | c.1101C>T p.D367= | Silent (SNP) | VAF 45/383 reads (12%) | catalogued as COSV57736120; called by muse, mutect2, varscan2
- FAM81B | c.198T>G p.L66= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV51985625; called by muse, mutect2
- FOXG1 | c.984C>T p.N328= | Silent (SNP) | VAF 52/282 reads (18%) | catalogued as rs774246700, COSV57396529; ClinVar: likely benign; called by muse, mutect2, varscan2
- GCNA | c.480C>T p.D160= | Silent (SNP) | VAF 18/189 reads (10%) | catalogued as rs184215123, COSV65466841; called by muse, mutect2
- GNAS | c.1170C>T p.T390= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58343068; called by muse, mutect2, varscan2
- HERC4 | c.3057C>T p.L1019= (on ENST00000395198 / NM_022079.3; = p.L1011= on NM_015601.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/199 reads (21%) | catalogued as COSV53019648; called by muse, mutect2, varscan2
- IGHG2 | c.291A>T p.T97= | Silent (SNP) | VAF 37/231 reads (16%) | called by muse, mutect2, varscan2
- IL23R | c.630G>T p.L210= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV100724857; called by muse, mutect2, varscan2
- ITGB8 | c.1260A>G p.R420= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV56012433; called by muse, mutect2, varscan2
- KRTAP4-3 | c.528G>A p.P176= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs777054986, COSV66940945; called by muse, mutect2, varscan2
- KTN1 | c.282T>C p.D94= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV68024990; called by muse, mutect2, varscan2
- LRFN2 | c.1950G>A p.K650= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1337034906, COSV57830053; called by muse, mutect2, varscan2
- MACF1 | c.8955G>A p.V2985= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs771710935, COSV57136547; called by muse, mutect2, varscan2
- MAP2 | c.3744G>T p.L1248= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV52302863; called by muse, mutect2, varscan2
- MARCHF7 | c.411A>C p.T137= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV52030488; called by muse, mutect2, varscan2
- MET | c.18G>T p.V6= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV59266429; called by muse, mutect2
- MRPS30 | c.504G>A p.E168= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV72361757; called by muse, mutect2, varscan2
- MYO7B | c.4947G>A p.L1649= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV101268329; called by muse, mutect2, varscan2
- NEFL | c.678G>C p.V226= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55338047, COSV99648093; called by muse, mutect2, varscan2
- NIPA2 | c.648C>A p.P216= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV57409915, COSV57413994; called by muse, mutect2, varscan2
- NLRP12 | c.2679G>A p.L893= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs542637537, COSV60752396; called by muse, mutect2, varscan2
- NPEPL1 | c.528C>T p.D176= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs367658268, COSV61940284; called by muse, mutect2, varscan2
- PKHD1 | c.10110A>G p.V3370= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV61889853; called by muse, mutect2, varscan2
- PLD5 | c.729G>A p.L243= (on ENST00000442594; = p.L181= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100139742, COSV100141854; called by muse, mutect2, varscan2
- PRAMEF12 | c.948G>A p.P316= | Silent (SNP) | VAF 50/206 reads (24%) | catalogued as rs746473825, COSV63216222; called by muse, mutect2, varscan2
- RALBP1 | c.1374G>A p.E458= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV50037740; called by muse, mutect2, varscan2
- SDK2 | c.3444G>A p.L1148= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV101168137; called by muse, mutect2, varscan2
- SLC15A4 | c.1137G>T p.L379= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV57163106; called by muse, mutect2, varscan2
- SLC25A13 | c.1047C>T p.I349= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs768322999, COSV55707417; called by muse, mutect2, varscan2
- SPHK1 | c.438G>A p.L146= (on ENST00000392496 / NM_001355139.2; = p.L160= on NM_021972.4) | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV60066429; called by muse, mutect2, varscan2
- SREBF2 | c.546G>A p.Q182= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs1367520847, COSV63332143; called by muse, mutect2, varscan2
- TEX37 | c.105G>A p.R35= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100304645; called by muse, mutect2, varscan2
- TMEFF1 | c.486A>G p.E162= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV58496241; called by muse, mutect2, varscan2
- UBN1 | c.2460A>G p.P820= | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as rs1469094246, COSV52171149; called by muse, mutect2, varscan2
- CCNQP1 | n.526G>A | RNA (SNP) | VAF 14/78 reads (18%) | catalogued as rs766572375; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415265 C>G | 5'Flank (SNP) | VAF 58/269 reads (22%) | catalogued as COSV52567332, COSV52568814; called by muse, mutect2, varscan2
- ELAPOR2 | c.741+665A>T | Intron (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99789196; called by muse, varscan2
- PXN | c.831+1972T>A | Intron (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- RNF217-AS1 | n.2693T>A | RNA (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- SNORA71A | n.79G>T | RNA (SNP) | VAF 43/190 reads (23%) | catalogued as rs527335952; called by muse, mutect2, varscan2
